Somatic mutation profile of tumor specimen TCGA-P5-A780-01A (aliquot TCGA-P5-A780-01A-12D-A32B-08) from TCGA case TCGA-P5-A780, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 44.2 years (16,161 days).
Specimen TCGA-P5-A780-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 277a87c4-06bb-4a41-987d-15d43545c0d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A780-10A (Blood Derived Normal), aliquot TCGA-P5-A780-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a688b8ec-c799-404f-9373-1bda4a448679

The open-access MAF lists 47 somatic variants for this specimen: 34 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 31, Silent 13, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/69 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 48/68 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANXA2 | c.684A>G p.V228= | Splice Region (SNP) | VAF 6/85 reads (7%) | catalogued as rs1444694338, COSV100222094; called by muse, mutect2
- APOB | c.335T>G p.L112W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99267107; called by muse, mutect2, varscan2
- ARHGAP21 | c.2821C>T p.R941* | Nonsense Mutation (SNP) | VAF 40/70 reads (57%) | catalogued as rs1390571927, COSV100256523; called by muse, mutect2, varscan2
- CCDC40 | c.1928A>G p.N643S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100884303; called by muse, mutect2, varscan2
- CENPE | c.7952C>G p.S2651C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1229388941, COSV54391695, COSV99478723; called by muse, mutect2
- EIF4B | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100016825, COSV100016936; called by muse, mutect2, varscan2
- FAM214A | c.1382A>G p.D461G | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99958323; called by muse, mutect2, varscan2
- GOLGA2 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100359387, COSV100360203; called by muse, mutect2, varscan2
- HPSE2 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs371339829; called by muse, mutect2, varscan2
- KCNT1 | c.2281C>T p.R761W (on ENST00000488444; = p.R780W on NM_020822.3) | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV53697089, COSV99706367; called by muse, mutect2
- LDOC1 | c.11A>G p.E4G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100983191; called by muse, mutect2, varscan2
- MAMLD1 | c.1409A>G p.Q470R | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99476430; called by muse, mutect2, varscan2
- MID1 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100452642; called by muse, mutect2, varscan2
- MSN | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100814279; called by muse, mutect2, varscan2
- MUC3A | c.8360T>C p.V2787A | Missense Mutation (SNP) | VAF 89/394 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.096); catalogued as COSV100115114; called by muse, mutect2, varscan2
- MYCBP2 | c.10456C>T p.R3486W (on ENST00000357337; = p.R3524W on NM_015057.5) | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100631279; called by muse, mutect2
- MYOF | c.3577G>A p.D1193N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs375965848; called by muse, mutect2, varscan2
- OR2A25 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 44/146 reads (30%) | catalogued as COSV101376409; called by muse, mutect2, varscan2
- OR2T33 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs755082412, COSV58814714; called by muse, mutect2, varscan2
- OSBPL6 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs149806664, COSV99507439; called by muse, mutect2, varscan2
- PARVB | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.557); catalogued as COSV100115102; called by muse, mutect2, varscan2
- PCDHB3 | c.1117C>G p.L373V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.094); catalogued as COSV99166087; called by muse, mutect2, varscan2
- PLCL2 | c.2896C>T p.R966C (on ENST00000615277 / NM_001144382.2; = p.R840C on NM_015184.5) | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1430864247; called by muse, mutect2, varscan2
- PRDM10 | c.2606C>T p.T869I | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV100456940; called by muse, mutect2, varscan2
- RGS3 | c.1567G>A p.G523R (on ENST00000350696 / NM_001282923.2; = p.G411R on NM_017790.4) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1305244481, COSV58276944, COSV58279473; called by muse, mutect2, varscan2
- RNF133 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.839); catalogued as COSV100411697; called by muse, mutect2, varscan2
- SAMD9 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101180329; called by muse, mutect2, varscan2
- SDR9C7 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1249676819, COSV99524682; called by muse, mutect2, varscan2
- SRXN1 | c.407T>G p.L136W | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101126510; called by muse, mutect2
- STYK1 | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs756733556, COSV99312116; called by muse, mutect2, varscan2
- TLR5 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs146146738; called by muse, mutect2, varscan2
- WWC3 | c.3179G>A p.S1060N | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as COSV101081665; called by muse, mutect2, varscan2
- ADCY4 | c.1845G>A p.T615= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs141339113; called by muse, mutect2, varscan2
- ARID1A | c.4401C>T p.P1467= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100252754; called by muse, mutect2, varscan2
- CACNA1D | c.669C>T p.G223= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs756461282, COSV55442986; called by muse, mutect2, varscan2
- CAPN6 | c.228G>A p.G76= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV60694144; called by muse, mutect2, varscan2
- CBLN4 | c.576G>A p.T192= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as rs780183162, COSV50352932; called by muse, mutect2, varscan2
- COL1A2 | c.1476T>C p.I492= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99800598; called by muse, mutect2, varscan2
- IPCEF1 | c.120C>T p.G40= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV54544213; called by muse, mutect2, varscan2
- PPP1R3A | c.489A>G p.L163= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99493777; called by muse, mutect2, varscan2
- SERPINB7 | c.615C>T p.V205= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs767405365, COSV100320973; called by muse, mutect2, varscan2
- SGO1 | c.1236A>T p.T412= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV99768427; called by muse, mutect2, varscan2
- TRPM3 | c.702C>T p.G234= (on ENST00000357533 / NM_001366142.2; = p.G79= on NM_020952.6) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs200167036, COSV62473823; called by muse, mutect2
- USP26 | c.2067T>C p.F689= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV100896721; called by muse, mutect2, varscan2
- ZNF681 | c.672A>G p.K224= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs749681721, COSV101267544; called by muse, mutect2, varscan2
